CCDI case PBBXSV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/93431c2d-b537-46c2-ad24-16a55ae1207a

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 3.4 years (1,249 days).

Biospecimens (3 samples)
- Sample 0DKIHR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKII3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DKIIB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
